Somatic mutation profile of tumor specimen 0DII45 from CCDI case PBBVLK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 12.9 years (4,715 days).
Specimen 0DII45: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 296dd99f-6b5e-4492-b33d-439e32c89e14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII36 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/449b126b-1269-4466-9edf-011039573911

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 3'Flank 1, 3'UTR 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 452/1035 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATF5 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 140/282 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs772931728, COSV61311679; called by muse, mutect2, varscan2
- PREX1 | c.4811G>A p.R1604Q | Missense Mutation (SNP) | VAF 272/595 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767487812, COSV64254197; called by muse, mutect2, varscan2
- ANKS1B | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 262/1000 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ARID1B | c.4736T>G p.V1579G | Missense Mutation (SNP) | VAF 224/468 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.057); called by muse, varscan2
- BTK | c.1566+7C>A | Splice Region (SNP) | VAF 74/325 reads (23%) | called by mutect2, varscan2
- C1orf185 | c.13A>C p.K5Q | Missense Mutation (SNP) | VAF 17/579 reads (3%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); called by muse, mutect2
- CACNA1B | c.5027C>T p.A1676V | Missense Mutation (SNP) | VAF 189/231 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PCDHB8 | c.2294T>G p.F765C | Missense Mutation (SNP) | VAF 135/366 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF449 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 210/480 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CREB3L2 | c.853T>C p.L285= | Silent (SNP) | VAF 316/753 reads (42%) | called by muse, mutect2, varscan2
- MTOR | c.6450C>T p.I2150= | Silent (SNP) | VAF 171/740 reads (23%) | catalogued as rs1052395251; called by muse, mutect2, varscan2
- PCDHA10 | c.2169G>A p.A723= | Silent (SNP) | VAF 195/481 reads (41%) | catalogued as COSV56480531; called by muse, mutect2, varscan2
- EBF4 | c.-22C>T | 5'UTR (SNP) | VAF 39/144 reads (27%) | called by muse, mutect2, varscan2
- KIF21B | chr1:200973570 G>A | 3'Flank (SNP) | VAF 79/590 reads (13%) | catalogued as rs568207572; called by muse, varscan2
- TXLNB | c.*66C>T | 3'UTR (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
